CGCI case HTMCP-02-03-01010 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/87d4156c-1b43-4e62-a9f3-8ed3709221b9

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 40 years; Vital status: Dead; Days to death: 407 days (1.1 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Squamous cell carcinoma, nonkeratinizing, NOS (the primary disease): ICD-O-3 morphology code: 8072/3; Tissue or organ of origin: Middle lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 40.2 years (14,672 days); Year of diagnosis: 2003; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC clinical T: T2; AJCC clinical N: NX; AJCC clinical M: MX; AJCC clinical stage: Stage II; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Prior malignancy: yes; Prior treatment: No; Residual disease: R0; Days to last follow up: 373 days (1.0 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 304 days; Days to treatment end: 329 days; Treatment dose: 25; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Pharmaceutical Therapy, NOS; adjuvant Pharmaceutical Therapy, NOS.
2. Lymphoma, NOS: Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: Prior primary.

Follow-up (4 entries)
- Days to follow up: 0 days; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 302 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to recurrence: 302 days.
- Days to follow up: 373 days (1.0 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day -2,430.

Other clinical attributes
- Day -2,430: Comorbidities: HIV/AIDS.
- Day -2,430: Risk factors: HIV/AIDS.
- Day 0: Weight: 69 kg; CD4 count: 3; Haart treatment indicator: Yes; HIV viral load: 57000.
- Day 0: Cdc hiv risk factors: Intravenous Drug User.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 29.

Biospecimens (2 samples)
- Sample HTMCP-02-03-01010-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-03-01010-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Squamous Cell Carcinoma, Non-Keratinizing; Tumor status: With tumor; Tobacco smoking age started: 15; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lost to follow-up: No; Tobacco smoking history indicator: 2; New tumor event diagnosis indicator: Yes.
- New tumor event: New tumor event site: Lung; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Middle lobe.
- History of disease: HIV status: Positive; Year of HIV diagnosis: 1996; Hbv test results: Negative; Hcv test results: Negative; HPV test results: Negative; Kshv hhv8 test results: Negative; Haart therapy at diagnosis: No; Haart therapy prior to diagnosis: Yes; Cd4 counts at diagnosis: 3; Cdc HIV risk group: IV drug user.
- Primary pathology: Lymph nodes examined: No.
- Treatments, Treatment: Therapy regimen: Recurrence; Treatment type: Radiation Therapy; Radiation therapy end: Yes; Radiation therapy total dosage: 25; Treatment best response: Clinical Progressive Disease.
- Treatments, Treatment, Extranodal radiation field list: Extranodal radiation field: Lymph Node, Hilar; Extranodal radiation field: Mediastinum.
